FM case AD5310 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Gallbladder.
https://portal.gdc.cancer.gov/cases/89d71233-d568-4ce0-95ea-ff2815f325c9

Male, 40.9 years: Adenocarcinoma, NOS (ICD-O-3 8140/3) of the gallbladder; metastasis biopsied or resected from the pelvis. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Metastatic.
